TCGA case TCGA-FJ-A3ZE — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/917961e2-78ad-4182-9cdb-5efb09808111

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Dead; Days to death: 324 days.

Diagnoses (4)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 65.3 years (23,866 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC pathologic N: N3; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 56 days; Days to treatment end: 99 days; Treatment dose: 5,600 cGy; Treatment outcome: Progressive Disease; Number of fractions: 28; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 62 days; Days to treatment end: 99 days; Treatment dose: 5,600 cGy; Number of fractions: 28; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 275 days; Days to treatment end: 299 days; Treatment dose: 3,000 cGy; Treatment outcome: Progressive Disease; Number of fractions: 10; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Age at diagnosis: 65.8 years (24,018 days); Days to diagnosis: 152 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Lymph node, NOS. Age at diagnosis: 65.8 years (24,018 days); Days to diagnosis: 152 days; Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Liver. Age at diagnosis: 65.8 years (24,018 days); Days to diagnosis: 152 days; Prior treatment: Yes.

Follow-up (6 entries)
- Days to follow up: 106 days; Disease response: With Tumor.
- Day 152 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 152 days.
- Day 152 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 152 days.
- Day 152 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 152 days.
- Days to follow up: 324 days; Disease response: With Tumor.
- ECOG performance status: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 109 kg; Height: 183 cm; BMI: 32.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Tobacco smoking quit year: 1986; Age at onset: 40.
- Chemical exposure type: Agent Orange; Occupation duration years: 25; Occupation type: Sales, Marketing and Public Relations Professionals.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FJ-A3ZE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-FJ-A3ZE-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-FJ-A3ZE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FJ-A3ZE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Retired; Occupation primary: Sales; Occupation primary chemical exposure: Agent Orange, Vietnam; Occupation primary industry: Food; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Lateral; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No.
- Metastatic site list: Metastasis site: Lymph node only.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Radiation treatment 2: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 324 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 324 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 152 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FJ-A3ZE-01A-11D-A23L-01): tumor purity 0.96, ploidy 1.91, whole-genome doublings 0.
